Surgical pathology report (de-identified scan), TCGA case TCGA-GI-A2C8, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-GI-A2C8-01A (Primary Tumor).

[page 1 of 4]
Final Pathologic Diagnosis:

A. Lymph node, level III, excision:

No evidence of malignancy (3 lymph nodes).

B. Breast, right, radical mastectomy:

Tumor (histologic type): Invasive ductal carcinoma.

Final size of invasive tumor: 2.4 cm

Scarff-Bloom-Richardson score:

Tubular score: 3

Nuclear score: 3

Mitotic score: 2

Total score: 8

In-situ component: Not identified.

Type: NA

Percent: NA

Architectural pattern: NA

Nuclear grade: NA

Comedo necrosis: NA

Angiolymphatic invasion: Present.

Skin and nipple: Tumor present in the dermis of the skin and nipple.

Dermal lymphatics: Angiolymphatic invasion is present.

Microcalcifications: Not identified.

Margins (distance \T\ size of involved area): Tumor is >1 cm from all margins.

Other findings:

Despite gross impression, microscopically the tumor does not invade the muscle or bone.

Lymph nodes (number positive/total number):

Ten lymph nodes negative for metastatic tumor (includes lymph nodes from part A).

Size of largest metastasis: NA

Number with extracapsular extension: NA

ER, PR: Positive, see case

HER2/neu: Negative, see case

pT4B, N0, MX

The examination of this case material and the preparation of this report were performed by the staff pathologist.

***Electronically Signed ***

, M.D.

, M.D.

Gross Description:

Received are two fixative filled containers labeled with the patient's name and medical record number.

Part A is additionally labeled "level 3 lymph nodes." The specimen consists of three fragments of yellow-tan fibroadipose tissue ranging from 1.1 to 2.2 cm in

ICD-0-3

carcinoma, infiltrating duct, NOS 8500/3

Site breast, NOS C50.9

lw
8/1/11

[page 2 of 4]
greatest dimension. Six lymph node candidates are identified, ranging from 0.3 to 1.4 cm.

- A1 four lymph nodes entirely submitted;
- A2 two lymph nodes entirely submitted.

Part B is additionally labeled "right radical mastectomy."

Specimen type: Radical mastectomy.

Specimen dimensions: 21.2 x 20.5 x 4.1 cm with a 6.5 x 5.4 x 1.7 cm portion of rib and chest wall.

Skin: A 20.6 x 10.2 cm ellipse of skin including the nipple is present. No scar is identified, however, there is significant puckering of the skin inferior to the nipple.

Location of lesion: The location is central.

Estimated size of lesion: The lesion is approximately 4.8 x 2.9 x 2.9 cm. (for final size, see Microscopic Description)

Appearance of lesion: The tumor is firm and white.

Distance from closest margin: The tumor appears to abut the inked deep margin.

Other findings: The tumor appears to involve the included pectoralis muscle.

Blocks submitted:

- B1 nipple;
- B2 tumor to inked deep margin and chest wall muscle;
- B3 tumor to skin and tumor greatest cross section;
- B4-5 additional representative tumor;
- B6 upper inner quadrant;
- B7 lower inner quadrant;
- B8 outer lower quadrant;
- B9 outer upper quadrant;
- B10 one axillary tail lymph node bisected, entirely submitted;
- B11 three axillary tail lymph nodes entirely submitted;
- B12 three axillary tail lymph nodes entirely submitted;
- B13 chest wall bone closest to tumor after decalcification.

, M.D.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

[page 3 of 4]
Final Pathologic Diagnosis:

A. Lymph node, level III, excision:

No evidence of malignancy (3 lymph nodes).

B. Breast, right, radical mastectomy:

Tumor (histologic type): Invasive ductal carcinoma.

Final size of invasive tumor: 2.4 cm

Scarff-Bloom-Richardson score:

Tubular score: 3

Nuclear score: 3

Mitotic score: 2

Total score: 8

In-situ component: Not identified.

Type: NA

Percent: NA

Architectural pattern: NA

Nuclear grade: NA

Comedo necrosis: NA

Angiolymphatic invasion: Present.

Skin and nipple: Tumor present in the dermis of the skin and nipple.

Dermal lymphatics: Angiolymphatic invasion is present.

Microcalcifications: Not identified.

Margins (distance \T\ size of involved area): Tumor is >1 cm from all margins.

Other findings:

Despite gross impression, microscopically the tumor does not invade the muscle or bone.

Lymph nodes (number positive/total number):

Ten lymph nodes negative for metastatic tumor (includes lymph nodes from part A).

Size of largest metastasis: NA

Number with extracapsular extension: NA

ER, PR: Positive, see case

HER2/neu: Negative, see case

pT4B, N0, MX

The examination of this case material and the preparation of this report were performed by the staff pathologist.

***Electronically Signed ***

, M.D.

, M.D.

Gross Description:

Received are two fixative filled containers labeled with the patient's name and medical record number.

Part A is additionally labeled "level 3 lymph nodes." The specimen consists of three fragments of yellow-tan fibroadipose tissue ranging from 1.1 to 2.2 cm in

[page 4 of 4]
greatest dimension. Six lymph node candidates are identified, ranging from 0.3 to 1.4 cm.

- A1 four lymph nodes entirely submitted;
- A2 two lymph nodes entirely submitted.

Part B is additionally labeled "right radical mastectomy."

Specimen type: Radical mastectomy.

Specimen dimensions: 21.2 x 20.5 x 4.1 cm with a 6.5 x 5.4 x 1.7 cm portion of rib and chest wall.

Skin: A 20.6 x 10.2 cm ellipse of skin including the nipple is present. No scar is identified, however, there is significant puckering of the skin inferior to the nipple.

Location of lesion: The location is central.

Estimated size of lesion: The lesion is approximately 4.8 x 2.9 x 2.9 cm. (for final size, see Microscopic Description)

Appearance of lesion: The tumor is firm and white.

Distance from closest margin: The tumor appears to abut the inked deep margin.

Other findings: The tumor appears to involve the included pectoralis muscle.

Blocks submitted:

- B1 nipple;
- B2 tumor to inked deep margin and chest wall muscle;
- B3 tumor to skin and tumor greatest cross section;
- B4-5 additional representative tumor;
- B6 upper inner quadrant;
- B7 lower inner quadrant;
- B8 outer lower quadrant;
- B9 outer upper quadrant;
- B10 one axillary tail lymph node bisected, entirely submitted;
- B11 three axillary tail lymph nodes entirely submitted;
- B12 three axillary tail lymph nodes entirely submitted;
- B13 chest wall bone closest to tumor after decalcification.

, M.D.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

Taken:

Source: NCI Genomic Data Commons file 9d68e6a7-3fe6-4c4d-82fc-f3da95014ae1 (TCGA-GI-A2C8.4AABCBD1-DF12-45E1-9307-21D6CB0894A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).